Surgical pathology report (de-identified scan), TCGA case TCGA-B2-4102, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-4102-01A (Primary Tumor).

SPECIMEN

Right kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right renal mass.

GROSS DESCRIPTION

The specimen is received unfixed, labeled "right kidney"
and consists of a radical nephrectomy specimen measuring

16

x 9 x 7 cm. On cut section the specimen contains a kidney measuring
12.5 x 7.7 cm. On the central portion of the kidney there is a
yellow tumor in the renal cortex measuring 5 x 3.2 cm. A portion of
the specimen is taken for research purposes. Sections after
fixation. RS-8.

MICROSCOPIC DESCRIPTION

Tumor type: Clear type renal cell carcinoma.
Tumor grade: 2 (out of 4; Fuhrman et al. AJSP 6:655,
)
Tumor size: 5 cm.
Renal capsule: Negative for malignancy.
Renal sinus: Negative for malignancy.
Vascular invasion: Absent.
Hilar margins: Negative for malignancy.
Kidney away from tumor: Unremarkable.
pTNM Stage: T1b

4

DIAGNOSIS

Kidney, right, resection:
Clear cell type renal cell carcinoma, Furhman grade 2.

DIAGNOSIS

--- End Of Report ---

Source: NCI Genomic Data Commons file 3c3f90af-6cfe-443e-b5cb-84897a781a5e (TCGA-B2-4102.FAA2C9CB-DB1B-4E15-8B19-B0178CC89F04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).